Somatic mutation profile of tumor specimen 0DBNBH from CCDI case PBBLKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,343 days).
Specimen 0DBNBH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e212d09-a2ed-4de3-8e29-71a675918a75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBNBP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f0ad72a-dbb0-4588-9ac7-b2598246d851

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.898C>G p.P300A | Missense Mutation (SNP) | VAF 208/1014 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.339); catalogued as COSV51952519; called by muse, varscan2
- H2BW2 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 172/490 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as rs782445611, COSV54582538; called by muse, varscan2
- C6orf118 | c.1265T>A p.I422N | Missense Mutation (SNP) | VAF 240/626 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- HDAC2 | c.86A>T p.H29L | Missense Mutation (SNP) | VAF 133/668 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- METTL14 | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 250/588 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); called by muse, varscan2
- MICAL2 | c.999C>A p.D333E | Missense Mutation (SNP) | VAF 107/997 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- NFE2L3 | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 481/872 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, varscan2
- CR1 | c.4134G>C p.G1378= | Silent (SNP) | VAF 325/875 reads (37%) | called by muse, varscan2
- EHD3 | c.45C>T p.P15= | Silent (SNP) | VAF 138/778 reads (18%) | called by muse, varscan2
- RUVBL1 | c.72G>A p.L24= | Silent (SNP) | VAF 192/800 reads (24%) | catalogued as COSV59474835; called by muse, varscan2
- B4GALNT1 | c.*1256C>A | 3'UTR (SNP) | VAF 94/522 reads (18%) | called by muse, varscan2
- MTMR12 | c.-55G>T | 5'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, varscan2
- MTMR12 | c.-56T>C | 5'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, varscan2
